Gene-level copy-number profile of tumor specimen TCGA-25-1321-01A from TCGA case TCGA-25-1321, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.7 years (23,987 days).
Specimen TCGA-25-1321-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8a0d15e0-9f45-4ec6-a19d-d4aa0c3bbf28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1321-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6f1ff83e-14b7-4aaa-ad1d-e56ffc68f7eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,708; copy number 2: 26,129; copy number 3: 20,246; copy number 4: 4,788; copy number 5: 588; copy number 6: 804; copy number 7: 143; copy number 8: 411.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1321-01): tumor purity 0.8, ploidy 4.6, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,946 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,493,515–119,275,973, 24 genes, copy number 6–7 (within-gene range 4–7): AL157902.2, VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17, AL391557.1, RNA5SP56, PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2.
- chr3:173,396,284–180,542,836, 88 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr5:19,233,366–24,910,695, 51 genes, copy number 5: HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA.
- chr6:60,281,444–63,616,361, 29 genes, copy number 5 (within-gene range 3–5): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18.
- chr11:49,915,013–55,839,738, 69 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–30,492,302, 753 genes, copy number 5–6 (broad region; genes not listed).
- chr12:32,985,838–33,718,217, 8 genes, copy number 5: ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1.
- chr14:18,333,726–23,934,568, 410 genes, copy number 8 (broad region; genes not listed).
- chr14:23,953,734–23,969,279, 1 gene, copy number 8: DHRS4.
- chr15:51,447,711–51,622,833, 1 gene, copy number 5 (within-gene range 2–5): DMXL2.
- chr15:51,681,492–55,176,739, 55 genes, copy number 5: SCG3, AC020892.1, AC020892.2, LYSMD2, TMOD2, AC026770.1, TMOD3, AC090971.5, Metazoa_SRP, AC090971.4, Y_RNA, AC090971.2, RNU6-90P, AC090971.1, AC090971.3, LEO1, MAPK6, MAPK6-DT, AC090970.2, AC090970.1, AC023906.5, AC023906.2, AC023906.1, BCL2L10, GNB5, AC023906.3, AC023906.4, Y_RNA, CERNA1, MYO5C, MIR1266, MYO5A, EEF1B2P1, ARPP19, AC025917.1, FAM214A, AC009754.1, AC009754.2, ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490, AC066614.1, WDR72, RNU2-53P, RNU6-449P, AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74, AC025272.1, AC011912.1.
- chr19:16,719,847–19,546,659, 148 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:23,222,755–23,274,221, 1 gene, copy number 6 (within-gene range 3–6): AC092329.3.
- chr19:23,255,053–24,163,425, 35 genes, copy number 6: IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr19:28,949,437–30,909,155, 38 genes, copy number 6: AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834.
- chr19:32,345,594–37,309,641, 234 genes, copy number 5–7 (broad region; genes not listed).
- chr19:37,314,868–37,315,620, 1 gene, copy number 5: AC016590.3.

Autosomal genes at a single copy (total copy number 1): 4,287. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
